Somatic mutation profile of tumor specimen C3L-06110-01 (aliquot CPT0319740006) from CPTAC case C3L-06110, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 55.2 years (20,176 days).
Specimen C3L-06110-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Shoulder; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 881ac5e5-e77f-40f6-830d-6a4f95c66bc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06110-31 (Blood Derived Normal), aliquot CPT0319800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3a9130c-11a8-4a75-8ba9-dc3c944d20bf

The open-access MAF lists 156 somatic variants for this specimen: 98 protein-altering or splice-affecting, 52 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 52, Nonsense Mutation 6, Intron 2, 3'UTR 2, 3'Flank 1, Frame Shift Del 1, Splice Site 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCC1 | c.3148G>A p.V1050M | Missense Mutation (SNP) | VAF 238/766 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.074); catalogued as rs898683852; called by muse, mutect2, varscan2
- ACSM4 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 191/447 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs755148242, COSV68067243; called by muse, mutect2, varscan2
- AR | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 310/789 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.575); catalogued as rs746338191; called by muse, mutect2, varscan2
- C16orf78 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 89/295 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs147852211, COSV54557684; called by muse, mutect2, varscan2
- C1R | c.838G>A p.E280K (on ENST00000536053 / NM_001354346.2; = p.E266K on NM_001733.7) | Missense Mutation (SNP) | VAF 234/550 reads (43%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.971); catalogued as rs766940345; called by muse, mutect2, varscan2
- CCDC184 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 56/774 reads (7%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs376072979; called by muse, mutect2
- CCDC39 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 103/175 reads (59%) | catalogued as rs1348126553, CM110032, COSV56486444, COSV99870843; called by muse, mutect2, varscan2
- CLOCK | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 127/340 reads (37%) | catalogued as COSV100011840; called by muse, mutect2, varscan2
- COX6B1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 147/415 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.393); catalogued as rs111638609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRISP2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 155/414 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV59253803; called by muse, mutect2, varscan2
- DEF6 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 48/476 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.664); catalogued as rs754987228, COSV57354568; called by muse, mutect2, varscan2
- DOT1L | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 233/687 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as rs370815654; called by muse, mutect2, varscan2
- DSC2 | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 128/366 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs866109928, COSV51868898; called by muse, mutect2, varscan2
- DSPP | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 175/495 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.044); catalogued as rs377628362; called by muse, mutect2, varscan2
- FANCA | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 56/506 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs761430527; called by muse, mutect2, varscan2
- FAT3 | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 143/394 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs370640653; called by muse, mutect2, varscan2
- FGD6 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 150/456 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1207050110; called by muse, mutect2, varscan2
- FLG2 | c.4645G>A p.D1549N | Missense Mutation (SNP) | VAF 227/625 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1170514392; called by muse, mutect2, varscan2
- FOXRED1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 136/398 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs150427279; called by muse, mutect2, varscan2
- GCN1 | c.5164G>A p.E1722K | Missense Mutation (SNP) | VAF 166/401 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56106890; called by muse, mutect2, varscan2
- GLI1 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 58/455 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV57362480; called by muse, mutect2, varscan2
- GPKOW | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 72/633 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1251414342; called by muse, mutect2, varscan2
- GRM7 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 170/278 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100736069; called by muse, mutect2, varscan2
- GRM8 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 231/594 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.727); catalogued as COSV100284005; called by muse, mutect2, varscan2
- HECW1 | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 300/746 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101222864; called by muse, mutect2, varscan2
- HS3ST4 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 56/820 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs967031128; called by muse, mutect2
- IFT57 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 108/181 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs753930289; called by muse, mutect2, varscan2
- KCNIP1 | c.136C>T p.R46W (on ENST00000411494 / NM_001034837.3; = p.R35W on NM_014592.4) | Missense Mutation (SNP) | VAF 158/402 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61080140; called by muse, mutect2, varscan2
- KHDC1L | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 104/324 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.022); catalogued as rs775522768; called by muse, mutect2, varscan2
- KLHL9 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1460504347, COSV100757055; called by muse, mutect2, varscan2
- KRT19 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 208/610 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs777703712, COSV54177940; called by muse, mutect2, varscan2
- KRT4 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 209/526 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs769322571, COSV53406168; called by muse, mutect2, varscan2
- MPLKIP | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 165/455 reads (36%) | catalogued as rs754149084; called by muse, mutect2, varscan2
- MUC16 | c.8273C>T p.S2758F | Missense Mutation (SNP) | VAF 160/377 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV67448876; called by muse, mutect2, varscan2
- NLRP5 | c.2101C>T p.R701C | Missense Mutation (SNP) | VAF 32/694 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs368914781, COSV66762342; called by muse, mutect2
- OR52D1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 156/470 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV59487259, COSV59487508; called by muse, mutect2, varscan2
- PLEKHO1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 132/367 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as rs141386276; called by muse, varscan2
- POSTN | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 170/426 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.047); catalogued as COSV101123545; called by muse, mutect2, varscan2
- POTEE | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 258/976 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.341); catalogued as rs543390483, COSV58225988, COSV58239043; called by muse, varscan2
- PRMT8 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 139/410 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as rs867638529, COSV54214160; called by muse, mutect2, varscan2
- RAG2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 57/380 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV100270996; called by muse, mutect2, varscan2
- RASA2 | c.1916C>T p.T639I | Missense Mutation (SNP) | VAF 93/152 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs766405631; called by muse, mutect2, varscan2
- SHH | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 311/714 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.061); catalogued as COSV51920105; called by muse, mutect2, varscan2
- SLC16A9 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 82/339 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs768442955; called by muse, mutect2, varscan2
- SLC34A2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 241/613 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65942867; called by muse, mutect2, varscan2
- SNTG2 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 35/406 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.033); catalogued as rs540473080; called by muse, mutect2
- SVOP | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 217/538 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747677894; called by muse, mutect2, varscan2
- TCHHL1 | c.1352G>A p.G451E | Missense Mutation (SNP) | VAF 207/531 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.113); catalogued as rs147543963, COSV64285236; called by muse, mutect2, varscan2
- TINAG | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 135/346 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs867360066, COSV52507137; called by muse, mutect2, varscan2
- TRAV4 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 17/494 reads (3%) | SIFT tolerated (0.66); PolyPhen benign (0.241); catalogued as rs1018332964; called by muse, mutect2
- WDFY4 | c.4304G>A p.R1435Q | Missense Mutation (SNP) | VAF 188/352 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs770531589, COSV57423868; called by muse, mutect2, varscan2
- ZBTB7C | c.1842G>A p.M614I | Missense Mutation (SNP) | VAF 28/530 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1366039169; called by muse, mutect2
- ZNF287 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 184/455 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV67688582; called by muse, mutect2, varscan2
- ABHD16A | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 246/653 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRG6 | c.2381G>A p.R794K | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALMS1 | c.8746C>T p.P2916S | Missense Mutation (SNP) | VAF 244/388 reads (63%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARID2 | c.2228T>A p.V743D | Missense Mutation (SNP) | VAF 88/570 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ASTN1 | c.2884G>A p.E962K | Missense Mutation (SNP) | VAF 208/574 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATXN7 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 86/132 reads (65%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BAG5 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 156/486 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 245/652 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C16orf96 | c.1906C>T p.Q636* | Nonsense Mutation (SNP) | VAF 212/624 reads (34%) | called by muse, mutect2, varscan2
- CCDC61 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- CFAP20DC | c.1813C>T p.L605F | Missense Mutation (SNP) | VAF 154/249 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.292); called by muse, mutect2
- DLG4 | c.1147G>A p.G383S (on ENST00000399506 / NM_001321075.3; = p.G426S on NM_001365.4) | Missense Mutation (SNP) | VAF 171/438 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- FA2H | c.377G>A p.W126* | Nonsense Mutation (SNP) | VAF 23/490 reads (5%) | called by muse, mutect2
- FCAMR | c.1727G>A p.G576E | Missense Mutation (SNP) | VAF 114/359 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- FSTL5 | c.1329G>A p.W443* | Nonsense Mutation (SNP) | VAF 73/222 reads (33%) | called by muse, mutect2, varscan2
- FTSJ1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 190/643 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GLI3 | c.4019C>T p.P1340L | Missense Mutation (SNP) | VAF 218/658 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HUWE1 | c.4628C>A p.P1543H | Missense Mutation (SNP) | VAF 133/360 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- IGHA1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 125/357 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAE | c.2385G>T p.E795D | Missense Mutation (SNP) | VAF 22/658 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2
- ITIH5 | c.1890G>A p.M630I | Missense Mutation (SNP) | VAF 215/398 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- JPH2 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 293/861 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MAGI3 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 225/359 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- MAP2K1 | c.119_145del p.L40_K48del | In Frame Del (DEL) | VAF 84/385 reads (22%) | called by mutect2, pindel, varscan2
- MAST3 | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 310/818 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- OR13C2 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2
- OTOGL | c.2493T>G p.C831W (on ENST00000547103; = p.C822W on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/357 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAPPA | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 156/333 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLD5 | c.738G>A p.M246I (on ENST00000442594; = p.M184I on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/300 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLEKHD1 | c.924-1G>A p.X308_splice | Splice Site (SNP) | VAF 125/372 reads (34%) | called by muse, mutect2, varscan2
- POMP | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 101/372 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PPP1R9A | c.2972_2979del p.Q991Lfs*15 | Frame Shift Del (DEL) | VAF 195/607 reads (32%) | called by mutect2, pindel, varscan2
- PRDM8 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 179/503 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PTCHD3 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 163/249 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGPD4 | c.2936C>T p.T979I | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SH3RF1 | c.2516C>T p.S839F | Missense Mutation (SNP) | VAF 154/476 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TCP11X2 | c.881G>A p.G294D | Missense Mutation (SNP) | VAF 47/1914 reads (2%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- TEX50 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 112/308 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- TRBV23-1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 135/379 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- TRPM5 | c.3242C>T p.T1081I | Missense Mutation (SNP) | VAF 224/551 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- TSPYL2 | c.415A>C p.S139R | Missense Mutation (SNP) | VAF 308/868 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZFHX4 | c.2992C>T p.H998Y | Missense Mutation (SNP) | VAF 197/493 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ZNF165 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 221/499 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- ZNF583 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACSBG2 | c.1251C>T p.G417= | Silent (SNP) | VAF 60/610 reads (10%) | catalogued as rs781503501, COSV53123951; called by muse, mutect2
- AFF2 | c.2247C>A p.I749= | Silent (SNP) | VAF 259/800 reads (32%) | catalogued as rs782451155, COSV53980226; called by muse, mutect2, varscan2
- AK7 | c.60G>A p.V20= | Silent (SNP) | VAF 164/435 reads (38%) | called by muse, mutect2, varscan2
- ANHX | c.139C>T p.L47= | Silent (SNP) | VAF 219/602 reads (36%) | called by muse, mutect2, varscan2
- ANKH | c.90G>A p.G30= | Silent (SNP) | VAF 57/278 reads (21%) | catalogued as rs762063944; called by muse, mutect2, varscan2
- ATP10D | c.2481C>T p.T827= | Silent (SNP) | VAF 166/500 reads (33%) | called by muse, mutect2, varscan2
- ATRX | c.2961G>A p.K987= | Silent (SNP) | VAF 167/495 reads (34%) | catalogued as COSV100970104; called by muse, mutect2, varscan2
- BAAT | c.6C>T p.I2= | Silent (SNP) | VAF 16/220 reads (7%) | called by muse, mutect2
- CACNA1A | c.330G>A p.A110= | Silent (SNP) | VAF 35/518 reads (7%) | catalogued as rs375486960, COSV64208410; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1A | c.42A>T p.G14= | Silent (SNP) | VAF 285/748 reads (38%) | called by muse, mutect2, varscan2
- CARD11 | c.966G>A p.R322= | Silent (SNP) | VAF 195/621 reads (31%) | called by muse, mutect2, varscan2
- CCDC168 | c.17415G>A p.Q5805= | Silent (SNP) | VAF 219/559 reads (39%) | called by muse, mutect2, varscan2
- CLDN18 | c.162C>T p.V54= | Silent (SNP) | VAF 249/381 reads (65%) | called by muse, mutect2, varscan2
- DGKI | c.1581C>T p.F527= | Silent (SNP) | VAF 14/444 reads (3%) | called by muse, mutect2
- DMRTB1 | c.270C>T p.V90= | Silent (SNP) | VAF 297/450 reads (66%) | called by muse, mutect2, varscan2
- ELAC2 | c.1281C>T p.L427= | Silent (SNP) | VAF 162/415 reads (39%) | called by muse, mutect2, varscan2
- FAM47A | c.63C>T p.Y21= | Silent (SNP) | VAF 68/755 reads (9%) | catalogued as COSV100649884; called by muse, mutect2
- GAL3ST1 | c.660C>T p.F220= | Silent (SNP) | VAF 76/583 reads (13%) | catalogued as rs145632139; called by muse, varscan2
- GPR153 | c.63C>T p.S21= | Silent (SNP) | VAF 260/380 reads (68%) | called by muse, mutect2, varscan2
- GPR35 | c.225C>T p.F75= | Silent (SNP) | VAF 212/346 reads (61%) | catalogued as rs372508109; called by muse, mutect2, varscan2
- HGF | c.1470G>A p.T490= | Silent (SNP) | VAF 121/424 reads (29%) | catalogued as rs372075114, COSV55945901; called by muse, mutect2, varscan2
- ITIH2 | c.2400G>A p.T800= | Silent (SNP) | VAF 108/209 reads (52%) | catalogued as rs769474192; called by muse, mutect2, varscan2
- LRCOL1 | c.469C>T p.L157= | Silent (SNP) | VAF 43/370 reads (12%) | called by muse, mutect2, varscan2
- MAGEA11 | c.1062G>A p.E354= | Silent (SNP) | VAF 54/723 reads (7%) | called by muse, mutect2
- MRGPRG | c.597C>T p.I199= | Silent (SNP) | VAF 309/784 reads (39%) | called by muse, mutect2, varscan2
- MYBPH | c.732C>T p.Y244= | Silent (SNP) | VAF 241/631 reads (38%) | catalogued as rs759565348; called by muse, mutect2, varscan2
- MYH11 | c.1476C>T p.F492= | Silent (SNP) | VAF 224/660 reads (34%) | called by muse, mutect2, varscan2
- NOS2 | c.2397G>A p.Q799= | Silent (SNP) | VAF 180/477 reads (38%) | catalogued as rs1017065324; called by muse, mutect2, varscan2
- OR5BS1P | c.630C>T p.T210= | Silent (SNP) | VAF 166/444 reads (37%) | catalogued as rs1565586566; called by muse, mutect2, varscan2
- PAK6 | c.903C>T p.S301= | Silent (SNP) | VAF 30/714 reads (4%) | catalogued as rs1396476338, COSV53045585; called by muse, mutect2
- PALLD | c.891C>T p.N297= | Silent (SNP) | VAF 148/386 reads (38%) | called by muse, mutect2, varscan2
- PCLO | c.13455G>A p.G4485= | Silent (SNP) | VAF 100/361 reads (28%) | catalogued as COSV61668293; called by muse, mutect2, varscan2
- PNMA6F | c.135C>T p.Y45= | Silent (SNP) | VAF 88/275 reads (32%) | called by muse, mutect2, varscan2
- PTPRH | c.3337T>C p.L1113= | Silent (SNP) | VAF 77/417 reads (18%) | called by muse, mutect2, varscan2
- REM1 | c.66C>T p.P22= | Silent (SNP) | VAF 69/889 reads (8%) | catalogued as COSV52430203, COSV52430217; called by muse, mutect2
- ROS1 | c.6759G>A p.L2253= | Silent (SNP) | VAF 141/355 reads (40%) | called by muse, mutect2, varscan2
- SLC17A4 | c.279A>T p.L93= | Silent (SNP) | VAF 122/404 reads (30%) | called by muse, mutect2, varscan2
- SLC22A25 | c.522C>T p.F174= | Silent (SNP) | VAF 119/345 reads (34%) | catalogued as rs763533661, COSV60599760; called by muse, mutect2, varscan2
- SLC41A1 | c.909G>A p.V303= | Silent (SNP) | VAF 219/561 reads (39%) | called by muse, mutect2, varscan2
- SLC45A4 | c.1518G>A p.R506= (on ENST00000517878 / NM_001286646.2; = p.R455= on NM_001080431.2) | Silent (SNP) | VAF 237/644 reads (37%) | called by muse, mutect2, varscan2
- SLC9A3 | c.417C>T p.N139= | Silent (SNP) | VAF 263/472 reads (56%) | catalogued as rs200892921; called by muse, mutect2, varscan2
- SYNJ1 | c.6G>A p.R2= | Silent (SNP) | VAF 165/449 reads (37%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2211G>A p.K737= | Silent (SNP) | VAF 10/352 reads (3%) | called by muse, mutect2
- TDRD15 | c.3930C>T p.F1310= | Silent (SNP) | VAF 163/278 reads (59%) | catalogued as rs942416867; called by muse, mutect2, varscan2
- TENM3 | c.1392G>A p.E464= | Silent (SNP) | VAF 237/702 reads (34%) | called by muse, mutect2, varscan2
- TEX13C | c.1932G>T p.L644= | Silent (SNP) | VAF 244/731 reads (33%) | called by muse, mutect2, varscan2
- THSD7B | c.2379C>T p.S793= | Silent (SNP) | VAF 138/219 reads (63%) | catalogued as COSV55721190; called by muse, mutect2, varscan2
- USP17L2 | c.273G>A p.E91= | Silent (SNP) | VAF 79/915 reads (9%) | called by muse, mutect2
- VPS37A | c.852C>T p.L284= | Silent (SNP) | VAF 21/294 reads (7%) | catalogued as rs1174262580, COSV100249015; called by muse, mutect2
- ZFHX3 | c.5634C>T p.N1878= | Silent (SNP) | VAF 267/714 reads (37%) | called by muse, mutect2, varscan2
- ZNF628 | c.1779C>T p.P593= | Silent (SNP) | VAF 277/781 reads (35%) | catalogued as rs550689648; called by muse, mutect2, varscan2
- ZNF808 | c.384C>T p.P128= | Silent (SNP) | VAF 229/575 reads (40%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-8505C>T | Intron (SNP) | VAF 44/281 reads (16%) | called by muse, mutect2, varscan2
- ARL10 | c.*1024T>A | 3'UTR (SNP) | VAF 32/418 reads (8%) | called by muse, mutect2
- BTNL2 | chr6:32394050 C>T | 3'Flank (SNP) | VAF 126/379 reads (33%) | called by muse, mutect2, varscan2
- FAAP24 | c.-106G>A | 5'UTR (SNP) | VAF 155/444 reads (35%) | called by muse, mutect2, varscan2
- FGFR3 | c.*241C>T | 3'UTR (SNP) | VAF 235/744 reads (32%) | catalogued as rs746217459; called by muse, mutect2, varscan2
- MT1G | c.97+87G>A | Intron (SNP) | VAF 274/697 reads (39%) | catalogued as rs759428562; called by muse, mutect2, varscan2
